Somatic mutation profile of tumor specimen TCGA-CR-7392-01A (aliquot TCGA-CR-7392-01A-11D-2012-08) from TCGA case TCGA-CR-7392, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.5 years (24,650 days).
Specimen TCGA-CR-7392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ed609ef-05e2-44a9-88f7-617b47539817.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7392-10A (Blood Derived Normal), aliquot TCGA-CR-7392-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d919e92-7504-4d53-beab-bd61925f7dff

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBRA1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100092674, COSV54052709; called by muse, mutect2, varscan2
- CA8 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs145210688, COSV100526650; called by muse, mutect2, varscan2
- DCAF6 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV99607462; called by muse, mutect2
- DEPDC5 | c.3799C>G p.L1267V (on ENST00000400246; = p.L1336V on NM_014662.5) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.166); catalogued as COSV99834306; called by muse, mutect2
- F9 | c.850A>T p.I284F | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as CD1411133, CD151340, COSV54380245, COSV99496305; called by muse, varscan2
- FJX1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100502797, COSV58553013; called by muse, mutect2, varscan2
- HAUS7 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs782353201, COSV57849468; called by muse, mutect2
- SDCBP | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV99232309; called by muse, mutect2
- SGCE | c.977G>A p.R326H (on ENST00000647096; = p.R290H on NM_003919.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs748001731, COSV99722132; called by muse, mutect2, varscan2
- TIGD3 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1374822373, COSV99361319; called by muse, mutect2
- MAFK | c.348C>T p.T116= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99867802; called by mutect2, varscan2
